ALCHEMIST case ALCH-B2AF — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/a214160b-b87c-4cd2-8b4b-850b92296e0a

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 68.2 years (24,919 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2AF-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2AF-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2AF-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 42; Percent tumor nuclei: 75; Percent normal cells: 29; Percent necrosis: 3; Percent stromal cells: 26; Percent lymphocyte infiltration: 18; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
